Surgical pathology report (de-identified scan), TCGA case TCGA-D5-5540, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-5540-01A (Primary Tumor).

Department of Cancer Pathology

Examination: Histopathological examination

Material: Multiple organ resection – segment of the large intestine

Unit in charge:

TCGA – D5 – 5540

Material collected on:

Material received on:

Clinical diagnosis: Tumour of the cecum, right sided hemicolectomia.

Examination performed on:

Macroscopic description:

7 cm length of the large intestine with perintestinal tissue sized 15 x 12 x 4 cm, 12 cm segment of the small intestine, and 3 cm appendix. Tumour sized 3.3 x 2.7 x 0.8 cm found in the mucosa. The lesion surrounding 50% of the intestine circumference placed 12 cm from the proximal cut end and 7 cm from the distal cut end.

Microscopic description:

Adenocarcinoma tubulare (G2). In filtra tio carcinomatosa telae adiposae pericolicae. Intestine ends free of neoplastic lesions.

Lymphonodulitis reactiva NO VIII.

Examination result:

Including test No. :

Adenocarcinoma tubulare coli.

(G2, Dukes B, Astler - Coller B2, pT3, pN0).

TUBULAR ADENOCARCINOMA OF THE COLON

Source: NCI Genomic Data Commons file 1ffdbdd2-81b0-4d4e-bd6d-9fffbc12197a (TCGA-D5-5540.4B0D96B0-30BD-416C-825A-349509305A6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).